Somatic mutation profile of tumor specimen TCGA-CV-6943-01A (aliquot TCGA-CV-6943-01A-11D-1912-08) from TCGA case TCGA-CV-6943, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,310 days).
Specimen TCGA-CV-6943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 072a3c85-0d7c-4126-9609-33906815198b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6943-10A (Blood Derived Normal), aliquot TCGA-CV-6943-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84f32a6f-17c0-40b0-a7c8-774672a217c7

The open-access MAF lists 49 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 6, Splice Site 3, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APBB1IP | c.284A>T p.H95L | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1346399812, COSV100774328; called by muse, mutect2
- CEP162 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100002542; called by muse, mutect2
- CNGA2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as rs1318609100, COSV61703233; called by muse, mutect2, varscan2
- DYNC2H1 | c.7669C>G p.Q2557E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100518010; called by muse, mutect2
- EMILIN1 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99565908, COSV99566484; called by muse, mutect2, varscan2
- EP300 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99607905; called by muse, mutect2, varscan2
- F13B | c.1388G>C p.R463T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV100803241, COSV66374953; called by muse, mutect2, varscan2
- FAM13C | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV99513366; called by muse, mutect2
- FAT1 | c.8323C>T p.Q2775* | Nonsense Mutation (SNP) | VAF 24/299 reads (8%) | catalogued as rs747465065, COSV101499172; called by muse, mutect2
- FLT3 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs573326027, COSV54052579; ClinVar: not provided; called by muse, mutect2, varscan2
- FXR1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99976258; called by muse, mutect2, varscan2
- GLYR1 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV100424131; called by muse, mutect2, varscan2
- HLA-A | c.895+1G>T p.X299_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as rs41547331, CS023211, CS098987, COSV100954330, COSV65141899; called by muse, mutect2, varscan2
- KIF18B | c.2242G>C p.E748Q (on ENST00000593135 / NM_001265577.2; = p.E760Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.277); catalogued as COSV100191923; called by muse, mutect2
- KIF1B | c.2095C>A p.L699I (on ENST00000377086 / NM_001365952.1; = p.L653I on NM_015074.3) | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV55815913, COSV99822858; called by muse, mutect2, varscan2
- MYBPC1 | c.2708G>A p.R903K (on ENST00000550270 / NM_206820.2; = p.R910K on NM_002465.4) | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1236806340, COSV62253305; called by muse, mutect2, varscan2
- MYH11 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55558090; called by muse, mutect2
- NCKAP5 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100490838; called by muse, mutect2
- NELFB | c.247-1G>C p.X83_splice | Splice Site (SNP) | VAF 14/148 reads (9%) | catalogued as COSV100546840; called by muse, mutect2
- OFD1 | c.517+1G>T p.X173_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100406801; called by muse, mutect2
- PKDREJ | c.2698A>G p.N900D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99478593; called by muse, mutect2, varscan2
- PLCE1 | c.4301G>A p.R1434Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53347013; called by muse, mutect2, varscan2
- RIMS2 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as COSV101344376; called by muse, mutect2, varscan2
- RNLS | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100907332, COSV64265876; called by muse, mutect2, varscan2
- SLFN11 | c.1966A>T p.R656* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV100390460; called by muse, varscan2
- SRCAP | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99349659; called by muse, mutect2, varscan2
- SRGAP1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV61901875; called by muse, mutect2, varscan2
- TCHHL1 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100916509; called by muse, mutect2
- TCTN2 | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315134; called by muse, mutect2, varscan2
- TRIM13 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100078229; called by muse, mutect2
- TSEN34 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99824685; called by muse, varscan2
- TSEN34 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99824686; called by muse, varscan2
- UBR5 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99640088; called by muse, mutect2
- ANGPT1 | c.86G>C p.S29T | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2
- CASP8 | c.531_533del p.Y178del (on ENST00000432109 / NM_033355.3; = p.Y210del on NM_001228.4) | In Frame Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- DDX52 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- JAK2 | c.1570_1592del p.P524Yfs*12 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ENO1 | c.246G>C p.L82= | Silent (SNP) | VAF 23/352 reads (7%) | catalogued as rs1352894713, COSV99318675; called by muse, mutect2
- KAT5 | c.744C>T p.S248= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV100383865; called by muse, mutect2, varscan2
- KIAA0100 | c.2439G>T p.R813= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV101197252, COSV66491587; called by muse, mutect2
- KLF1 | c.84C>T p.L28= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99322337; called by mutect2, varscan2
- MYOM2 | c.891C>G p.L297= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100037072; called by muse, mutect2
- NUP98 | c.5298T>C p.D1766= (on ENST00000359171 / NM_001365126.1; = p.D1749= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1227263019, COSV99167320; called by muse, mutect2, varscan2
- OR4N2 | c.786C>T p.F262= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs1433522691, COSV100269488; called by muse, mutect2, varscan2
- RAPGEF3 | c.813C>T p.T271= (on ENST00000389212; = p.T229= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/381 reads (7%) | catalogued as rs1002833104, COSV99406021; called by muse, mutect2
- RBM15B | c.1638G>A p.L546= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100081981; called by muse, mutect2
- TAF7L | c.1388G>A p.*463= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100229411; called by muse, mutect2, varscan2
